Gene-level copy-number profile of tumor specimen C3N-03460-02 (profiled together with C3N-03460-03) from CPTAC case C3N-03460, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.7 years (24,349 days).
Specimen C3N-03460-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f4f0cf61-c5e7-41ff-b0e4-35a6f12f6c88.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03460-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/58d03b2a-3eb6-44af-bf6d-5f9bb5c4853e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 276; copy number 2: 56,337; copy number 3: 1,604; copy number 4: 76; copy number 5: 71; copy number 6: 9; copy number 7: 1; copy number 10: 2; copy number 16: 1; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 85 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,851,791–89,852,497, 1 gene, copy number 5: IGKV2D-40.
- chr2:90,309,230–91,621,421, 7 genes, copy number 6 (within-gene range 3–6): AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr14:18,333,726–18,419,273, 3 genes, copy number 7–24: CR383658.1, CR383658.2, BNIP3P6.
- chr21:7,744,962–13,120,807, 74 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 247. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
